Somatic mutation profile of tumor specimen TCGA-HU-8245-01A (aliquot TCGA-HU-8245-01A-11D-2340-08) from TCGA case TCGA-HU-8245, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 72.6 years (26,521 days).
Specimen TCGA-HU-8245-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ab22889-017f-46aa-a0b6-234f4cf72f3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8245-10A (Blood Derived Normal), aliquot TCGA-HU-8245-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b72cf80-9341-4643-ae65-06e8242c27a2

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Frame Shift Del 5, Splice Site 4, Nonsense Mutation 3, Splice Region 2, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3183del p.K1061Nfs*65 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as CD057020; called by mutect2, pindel, varscan2
- CACNA1A | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64209207; called by muse, mutect2, varscan2
- CACNA1E | c.6638C>A p.S2213Y (on ENST00000367573 / NM_001205293.3; = p.S2170Y on NM_000721.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV62384003, COSV62412863; called by muse, mutect2, varscan2
- CACNA1I | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750837338, COSV100362038, COSV60807547; called by muse, mutect2, varscan2
- CCN5 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763203992, COSV51936580; called by muse, mutect2, varscan2
- CCNA1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV55221957; called by mutect2, varscan2
- CDH12 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776551575, COSV66395887, COSV66397843; called by muse, mutect2, varscan2
- COL11A1 | c.1311T>A p.G437= | Splice Region (SNP) | VAF 12/75 reads (16%) | catalogued as COSV62193512; called by muse, mutect2, varscan2
- CPXM1 | c.2165T>G p.L722R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV66046485; called by muse, mutect2, varscan2
- DDR1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV61324239; called by muse, mutect2, varscan2
- DEFB110 | c.56-2A>G p.X19_splice | Splice Site (SNP) | VAF 16/133 reads (12%) | catalogued as rs150306060; called by muse, mutect2, varscan2
- EPHA5 | c.395T>G p.F132C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56645847, COSV99900635, COSV99902166; called by muse, mutect2, varscan2
- FZD10 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV57475320; called by muse, mutect2, varscan2
- GABBR2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV52316120; called by muse, varscan2
- GRIN3A | c.1468G>T p.V490F | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.19); catalogued as COSV62457229; called by muse, mutect2, varscan2
- GUCY2F | c.407C>G p.S136W | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV54297945, COSV54306707; called by muse, mutect2, varscan2
- HMCN1 | c.2450A>G p.Q817R | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.759); catalogued as COSV54931341; called by muse, mutect2
- HNRNPDL | c.867dup p.L290Ifs*15 | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | catalogued as rs1202858345; called by mutect2, varscan2
- IRF2 | c.365-2A>T p.X122_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | catalogued as COSV66930289; called by muse, mutect2, varscan2
- ITGAV | c.1682dup p.L562Tfs*5 | Frame Shift Ins (INS) | VAF 74/144 reads (51%) | catalogued as rs1209653205; called by mutect2, varscan2
- ITPR3 | c.2251A>C p.I751L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.591); catalogued as COSV65413683; called by muse, mutect2
- KRT28 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs371042085, COSV60684804; called by muse, mutect2, varscan2
- LPO | c.419C>G p.T140S | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as COSV51861711; called by muse, mutect2, varscan2
- LRRC7 | c.2858G>A p.R953H (on ENST00000651989 / NM_001370785.2; = p.R920H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs141932871; called by muse, mutect2, varscan2
- MAP2K4 | c.219-2A>G p.X73_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV62259864; called by muse, mutect2, varscan2
- MAP3K11 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV58421327; called by muse, mutect2, varscan2
- MMP10 | c.1156A>G p.K386E | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54247373; called by muse, mutect2, varscan2
- MSANTD4 | c.741T>G p.H247Q | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV57285430, COSV57286311; called by muse, mutect2, varscan2
- MYH15 | c.4343G>A p.R1448H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs367795542; called by muse, mutect2, varscan2
- NAA20 | c.490T>C p.S164P | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58549079; called by muse, mutect2, varscan2
- NEB | c.14980G>A p.A4994T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51449817, COSV51458575; called by muse, mutect2, varscan2
- OPRK1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs186551684; called by muse, mutect2, varscan2
- OR9Q2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV61112579; called by muse, mutect2, varscan2
- OXGR1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53658341; called by muse, mutect2, varscan2
- PCDH1 | c.2023C>G p.R675G | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618264; called by muse, mutect2, varscan2
- PRMT9 | c.1673A>G p.D558G | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59361046; called by muse, mutect2, varscan2
- PSMB1 | c.24T>A p.Y8* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV51531661; called by muse, mutect2
- QPCT | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 100/185 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV58120374, COSV58120914; called by muse, mutect2, varscan2
- RIOX2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 45/212 reads (21%) | catalogued as COSV57724722; called by muse, mutect2, varscan2
- SAMSN1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs775995897, COSV53470526; called by muse, mutect2, varscan2
- SLC26A6 | c.1200C>A p.C400* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV56574705; called by muse, mutect2
- SLC2A1 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV65288159; called by muse, mutect2, varscan2
- SMARCB1 | c.781T>G p.F261V (on ENST00000263121; = p.F307V on NM_003073.5) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54101375; called by muse, mutect2, varscan2
- SMG8 | c.2189C>A p.T730N | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56286646; called by muse, mutect2, varscan2
- TMEM138 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53651458, COSV53653582; called by muse, mutect2, varscan2
- TP53 | c.721del p.S241Pfs*6 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by mutect2, pindel, varscan2
- TRHR | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV61233299; called by muse, mutect2, varscan2
- TRMT10B | c.186G>A p.S62= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs373829295; called by muse, mutect2
- TUBB2B | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV52533427, COSV52534306; called by muse, mutect2, varscan2
- UNC5C | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777197285, COSV71659131; called by muse, mutect2, varscan2
- WDR17 | c.3510A>C p.L1170F | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54581340; called by muse, mutect2, varscan2
- WHRN | c.1250G>T p.S417I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV54334043; called by muse, mutect2, varscan2
- YIF1B | c.302A>T p.D101V (on ENST00000339413 / NM_001039673.3; = p.D86V on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV56651523, COSV56651610; called by muse, mutect2, varscan2
- ZNF318 | c.400-1G>C p.X134_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV58592516; called by muse, mutect2
- BAHD1 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA1549L | c.3559C>A p.L1187M (on ENST00000321505; = p.L1484M on NM_012194.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP10 | c.187del p.I63Sfs*12 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- TLCD1 | c.725_729del p.D242Vfs*4 | Frame Shift Del (DEL) | VAF 35/279 reads (13%) | called by mutect2, pindel, varscan2
- ZNF211 | c.1419_1420del p.R473Sfs*9 (on ENST00000347302 / NM_198855.4; = p.R486Sfs*9 on NM_006385.5) | Frame Shift Del (DEL) | VAF 34/174 reads (20%) | called by pindel, varscan2
- ANKS1B | c.513C>T p.Y171= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs376764060, COSV61369743; called by muse, mutect2, varscan2
- CAMTA1 | c.2490C>T p.S830= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV57921334; called by muse, mutect2, varscan2
- CCDC102A | c.1206C>T p.C402= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as rs202155801, COSV50778775; called by muse, mutect2, varscan2
- EMC8 | c.585T>C p.N195= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53668273; called by muse, mutect2, varscan2
- FRMD4A | c.2913C>T p.S971= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV62268419; called by muse, mutect2, varscan2
- GIMAP5 | c.694A>C p.R232= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV57530325; called by muse, mutect2, varscan2
- IGSF9 | c.165C>T p.I55= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs143816509; called by muse, mutect2, varscan2
- KCNF1 | c.1119C>T p.Y373= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs775238006, COSV54465142, COSV99705444; called by muse, mutect2, varscan2
- KCNH1 | c.1221C>T p.D407= (on ENST00000271751 / NM_172362.3; = p.D380= on NM_002238.4) | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs138866428; called by muse, mutect2, varscan2
- KLHDC7B | c.1263C>T p.Y421= (on ENST00000395676; = p.Y1062= on NM_138433.5) | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as rs930545178, COSV67464998; called by muse, mutect2, varscan2
- PDE6A | c.1431G>A p.K477= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as COSV54927396; called by muse, mutect2, varscan2
- RSPO1 | c.255C>T p.D85= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs766588002, COSV62975106; called by muse, mutect2, varscan2
- TNXB | c.9606G>T p.L3202= (on ENST00000647633; = p.L2955= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs745510765; called by muse, mutect2, varscan2
- ZC3H7B | c.1311C>T p.G437= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs761300741, COSV60964164; called by muse, mutect2, varscan2
- BRD4 | c.2158+456G>A | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as rs199764678; called by muse, mutect2, varscan2
- TTN | c.10303+1368G>T | Intron (SNP) | VAF 62/115 reads (54%) | catalogued as COSV60275166; called by muse, mutect2, varscan2
